CPTAC case C259161 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/996413b0-bbd5-4df5-9222-6dfb57c53c58

Demographics
Sex at birth: male; Age at index: 72 years; Vital status: Dead; Days to death: 113 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Gliosarcoma: ICD-O-3 morphology code: 9442/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Tumor grade: G4; Residual disease: R2; Last known disease status: With tumor; Days to last known disease status: 113 days; Progression or recurrence: yes; Days to recurrence: 50 days; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Cigarettes per day: 0; Alcohol history: No.

Biospecimens (6 samples)
- Samples 1104787, 1105250, SM-JU32P (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples 1104793, 1105257 (2 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 1105283: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
